Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAEQ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAEQ-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 3/13/14

Direct dial
Mobile:
Internal postal address
E-mail
Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 5,5 cm; invasion in rete testis; pagetoid invasion in rete testis; no angio-invasion; no invasion in epididymis.

Date of tumor procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 3e618aff-8b78-41c6-ab55-c49b270d640d (TCGA-2G-AAEQ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).